Somatic mutation profile of tumor specimen TCGA-60-2698-01A (aliquot TCGA-60-2698-01A-01W-0877-08) from TCGA case TCGA-60-2698, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.4 years (22,800 days).
Specimen TCGA-60-2698-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa721166-aaf7-4406-a3a8-49549457e59f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2698-11A (Solid Tissue Normal), aliquot TCGA-60-2698-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1836886f-9165-4dc1-afed-4f9a7c929c01

The open-access MAF lists 1,063 somatic variants for this specimen: 803 protein-altering or splice-affecting, 233 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 696, Silent 233, Nonsense Mutation 75, Splice Site 12, Frame Shift Del 12, Intron 10, RNA 10, Splice Region 4, 5'UTR 3, Frame Shift Ins 3, 3'Flank 2, Nonstop Mutation 1.

Variants (750 of 1,063; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 42/92 reads (46%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.515C>G p.S172C | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs1407810587, COSV52708092; called by muse, mutect2, varscan2
- AASS | c.811C>G p.L271V | Missense Mutation (SNP) | VAF 44/466 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as COSV62790735; called by muse, mutect2
- ABCB1 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55955416; called by muse, mutect2, varscan2
- ABCB1 | c.579C>G p.F193L | Missense Mutation (SNP) | VAF 104/429 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as rs770008344, COSV55955423; called by muse, mutect2, varscan2
- ABCD2 | c.1678C>G p.Q560E | Missense Mutation (SNP) | VAF 95/213 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1389158925, COSV58052864; called by muse, mutect2, varscan2
- ABL1 | c.2576C>G p.S859* | Nonsense Mutation (SNP) | VAF 7/9 reads (78%) | catalogued as COSV59334680; called by muse, mutect2, varscan2
- ACAD9 | c.1791G>C p.Q597H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV58308540; called by muse, mutect2, varscan2
- ACSL6 | c.794del p.P265Rfs*37 (on ENST00000379240; = p.P290Rfs*37 on NM_015256.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as COSV57297826; called by mutect2, pindel, varscan2
- ACSM4 | c.629C>G p.S210C | Missense Mutation (SNP) | VAF 22/271 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101257011, COSV68068299; called by muse, mutect2
- ACTL8 | c.880C>G p.H294D | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV64861916, COSV64862853; called by muse, mutect2, varscan2
- ADAM10 | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53052740; called by muse, mutect2, varscan2
- ADAM23 | c.2128G>A p.D710N | Missense Mutation (SNP) | VAF 59/325 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as rs906482356, COSV52213597, COSV52214832, COSV52220227; called by muse, mutect2, varscan2
- ADAM7 | c.224T>G p.L75R | Missense Mutation (SNP) | VAF 201/428 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.062); catalogued as COSV51542422; called by muse, mutect2, varscan2
- ADAMTS10 | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.603); catalogued as COSV54356382; called by muse, mutect2, varscan2
- ADAMTS12 | c.4063G>T p.D1355Y | Missense Mutation (SNP) | VAF 87/300 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100711651, COSV61257949, COSV61268012; called by muse, mutect2, varscan2
- ADAMTS12 | c.3971A>T p.E1324V | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV61268024; called by muse, mutect2, varscan2
- ADAMTS16 | c.1930A>C p.S644R | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs777183350, COSV56995789; called by muse, mutect2, varscan2
- ADAMTS3 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV54395451; called by muse, mutect2, varscan2
- ADAMTS6 | c.2114G>A p.R705K | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV66861605; called by muse, mutect2, varscan2
- ADAMTS6 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV66861608; called by muse, mutect2
- ADAMTSL3 | c.2939A>T p.Y980F | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54455715; called by muse, mutect2
- ADD3 | c.1795C>T p.Q599* | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as COSV53323673; called by muse, mutect2
- ADGRB3 | c.4012G>T p.E1338* | Nonsense Mutation (SNP) | VAF 21/151 reads (14%) | catalogued as COSV53251086; called by muse, mutect2, varscan2
- ADGRE1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 89/227 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV51677645; called by muse, mutect2, varscan2
- ADGRG7 | c.2246C>T p.S749L | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV56298412, COSV56298546; called by muse, mutect2, varscan2
- ADGRL4 | c.1267G>C p.D423H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV66062734; called by muse, mutect2, varscan2
- ADGRV1 | c.17279G>A p.G5760E | Missense Mutation (SNP) | VAF 127/210 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67989140; called by muse, mutect2, varscan2
- AHI1 | c.1583C>T p.S528L | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55623723; called by muse, mutect2, varscan2
- AKAP3 | c.2420C>T p.S807L | Missense Mutation (SNP) | VAF 232/601 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV50539351; called by muse, mutect2, varscan2
- AKR1B10 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV62055631, COSV62055914; called by muse, mutect2, varscan2
- AL121899.2 | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 140/422 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1264352447, COSV67351259; called by muse, mutect2, varscan2
- ALCAM | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 95/239 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60250848; called by muse, mutect2, varscan2
- ALDH1A2 | c.1485G>T p.M495I | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV51084322; called by muse, mutect2, varscan2
- ALDH1A2 | c.1485-1G>A p.X495_splice | Splice Site (SNP) | VAF 51/189 reads (27%) | catalogued as COSV99991197; called by muse, mutect2, varscan2
- ALG8 | c.285G>C p.L95F | Missense Mutation (SNP) | VAF 15/374 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55201152; called by muse, mutect2
- AMER3 | c.1156G>T p.G386C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58467956; called by muse, mutect2, varscan2
- ANK3 | c.7202A>T p.E2401V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55066348; called by muse, mutect2, varscan2
- ANKRD12 | c.4994A>C p.N1665T | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV50832513; called by muse, mutect2, varscan2
- ANKRD12 | c.5710C>T p.R1904* | Nonsense Mutation (SNP) | VAF 31/219 reads (14%) | catalogued as rs891449557, COSV50832535; called by muse, mutect2, varscan2
- ANKRD30A | c.3487C>T p.Q1163* (on ENST00000611781; = p.Q1107* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 158/383 reads (41%) | catalogued as rs1436766225, COSV100653796, COSV64614228; called by muse, mutect2, varscan2
- APBA2 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV67105146; called by muse, mutect2, varscan2
- APPL1 | c.1304C>G p.S435C | Missense Mutation (SNP) | VAF 123/279 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV55701849; called by muse, mutect2, varscan2
- ARAF | c.711G>C p.Q237H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV51693612; called by muse, mutect2, varscan2
- ARHGAP21 | c.3166C>T p.R1056* | Nonsense Mutation (SNP) | VAF 24/142 reads (17%) | catalogued as COSV57602405; called by muse, mutect2, varscan2
- ARHGDIB | c.597G>A p.W199* | Nonsense Mutation (SNP) | VAF 35/718 reads (5%) | catalogued as rs778988055, COSV56763907; called by muse, mutect2
- ARID1B | c.5362G>C p.D1788H | Missense Mutation (SNP) | VAF 75/261 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV51668705, COSV51674034; called by muse, mutect2, varscan2
- ARID2 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.112); catalogued as COSV57608330; called by muse, mutect2, varscan2
- ARID2 | c.3298C>G p.Q1100E | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV57601004, COSV57608342; called by muse, mutect2, varscan2
- ARL6 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 53/285 reads (19%) | catalogued as COSV60117994; called by muse, mutect2, varscan2
- ARMH4 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV50767350, COSV99958351; called by muse, mutect2, varscan2
- ASB11 | c.452T>A p.L151Q | Missense Mutation (SNP) | VAF 56/324 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV60355691; called by muse, mutect2, varscan2
- ASCC3 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV61230646; called by muse, mutect2, varscan2
- ASH1L | c.3326C>A p.S1109Y | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as COSV64210064; called by muse, mutect2, varscan2
- ASIC2 | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs757867324, COSV56765303, COSV99859063; called by muse, mutect2
- ASPH | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as COSV62860209; called by muse, mutect2, varscan2
- ASTN1 | c.2201A>G p.N734S | Missense Mutation (SNP) | VAF 38/592 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV56074788; called by muse, mutect2
- ATAD2 | c.2206G>C p.D736H | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54883185; called by muse, mutect2, varscan2
- ATAD5 | c.2794-1G>T p.X932_splice | Splice Site (SNP) | VAF 33/149 reads (22%) | catalogued as COSV58976179; called by muse, mutect2, varscan2
- ATG9A | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.968); catalogued as COSV60133844; called by muse, mutect2
- ATP10A | c.497del p.G166Efs*41 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | catalogued as COSV63518896; called by mutect2, pindel, varscan2
- ATP11A | c.3086G>C p.W1029S | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as COSV52115915; called by muse, mutect2, varscan2
- ATP2A3 | c.1340G>T p.C447F | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV59231253; called by muse, mutect2, varscan2
- ATP6V0A4 | c.351G>C p.L117F | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV59477480; called by muse, mutect2, varscan2
- ATXN7 | c.590G>C p.G197A | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1559654831, COSV55752761; called by muse, mutect2
- AVPR1B | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 27/62 reads (44%) | catalogued as COSV65638311; called by muse, mutect2, varscan2
- AXDND1 | c.1199G>C p.W400S | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62644664; called by muse, mutect2, varscan2
- B3GALT2 | c.637C>G p.H213D | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV66464283; called by muse, mutect2, varscan2
- BARD1 | c.1980C>G p.S660R | Missense Mutation (SNP) | VAF 110/341 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53613664; called by muse, mutect2, varscan2
- BBOX1 | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV54192138; called by muse, mutect2, varscan2
- BCL6 | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.253); catalogued as COSV51653431; called by muse, mutect2, varscan2
- BIRC6 | c.4606G>T p.D1536Y | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs769833188, COSV70202113; called by muse, mutect2, varscan2
- BMPER | c.1552G>C p.D518H | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as rs750210912, COSV51819440, COSV51823831; called by muse, mutect2, varscan2
- BPIFB4 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1191459280, COSV64951615; called by muse, mutect2
- BRPF3 | c.403G>C p.A135P | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.825); catalogued as COSV100325551, COSV60208258; called by muse, mutect2, varscan2
- BRWD1 | c.6818C>G p.S2273C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as COSV59000362, COSV59000786; called by muse, mutect2, varscan2
- BRWD3 | c.4462C>T p.H1488Y | Missense Mutation (SNP) | VAF 73/429 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64750342; called by muse, mutect2, varscan2
- BTK | c.496C>A p.Q166K | Missense Mutation (SNP) | VAF 128/225 reads (57%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as CM980267, COSV58121433; called by muse, mutect2, varscan2
- BTN3A2 | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV62687651; called by muse, mutect2
- BYSL | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.042); catalogued as COSV57828914; called by muse, mutect2, varscan2
- C12orf50 | c.350A>G p.E117G | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV53894759, COSV53896658; called by muse, mutect2, varscan2
- C12orf50 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 69/244 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV53895860, COSV53896425; called by muse, mutect2, varscan2
- C1orf100 | c.88C>G p.Q30E | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV57373251; called by muse, mutect2, varscan2
- C1orf141 | c.227C>G p.S76* | Nonsense Mutation (SNP) | VAF 45/409 reads (11%) | catalogued as COSV63992921; called by muse, mutect2, varscan2
- C2orf16 | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as COSV62676761; called by muse, mutect2, varscan2
- C2orf78 | c.2051C>A p.P684Q | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs756767934, COSV101280987, COSV68518293; called by muse, mutect2, varscan2
- C4orf51 | c.239C>G p.S80* | Nonsense Mutation (SNP) | VAF 56/138 reads (41%) | catalogued as COSV71264425; called by muse, mutect2, varscan2
- C6orf118 | c.490C>G p.P164A | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0.013); catalogued as COSV57814483, COSV57816483; called by muse, mutect2, varscan2
- CA10 | c.829C>G p.Q277E | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV53354543, COSV53357617; called by muse, mutect2, varscan2
- CACHD1 | c.3476G>C p.R1159T | Missense Mutation (SNP) | VAF 92/421 reads (22%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.916); catalogued as COSV51556102; called by muse, mutect2, varscan2
- CACNA1B | c.3957G>C p.E1319D | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV53134436; called by muse, mutect2
- CACNA1C | c.5053G>C p.E1685Q | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV59739665; called by muse, mutect2
- CACNA1G | c.5452G>C p.E1818Q | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.439); catalogued as COSV61731412; called by muse, mutect2
- CARS1 | c.1612A>G p.R538G | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as COSV53456656; called by muse, mutect2, varscan2
- CASP10 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.476); catalogued as COSV53779261; called by muse, mutect2
- CASP2 | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 48/108 reads (44%) | catalogued as COSV60082693; called by muse, mutect2, varscan2
- CATSPER3 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV50947512; called by muse, mutect2, varscan2
- CAV3 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.147); catalogued as rs773309037, COSV57479778; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCAR1 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 56/256 reads (22%) | catalogued as COSV56271340; called by muse, mutect2, varscan2
- CCDC112 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV65473496; called by muse, mutect2, varscan2
- CCDC113 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1034980690, COSV54686714; called by muse, mutect2
- CCDC146 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 20/317 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53550951; called by muse, mutect2
- CCDC170 | c.1861A>G p.R621G | Missense Mutation (SNP) | VAF 81/400 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53342767, COSV53345757; called by muse, mutect2, varscan2
- CCDC191 | c.2148G>C p.K716N | Missense Mutation (SNP) | VAF 81/442 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs888443284, COSV55673772; called by muse, mutect2, varscan2
- CCDC24 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV58844510; called by muse, mutect2, varscan2
- CCDC47 | c.372+1G>C p.X124_splice | Splice Site (SNP) | VAF 30/214 reads (14%) | catalogued as COSV56723555; called by muse, mutect2, varscan2
- CCDC51 | c.933G>C p.R311S | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV56491560; called by muse, mutect2, varscan2
- CCL3 | c.101G>C p.C34S | Missense Mutation (SNP) | VAF 85/315 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs190805628; called by muse, mutect2, varscan2
- CCPG1 | c.1981C>T p.Q661* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as COSV51242573; called by muse, mutect2, varscan2
- CCPG1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV60526317; called by muse, mutect2
- CCSER1 | c.1798A>T p.S600C | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61443743; called by muse, varscan2
- CCSER1 | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748961219, COSV61443763; called by muse, varscan2
- CD163L1 | c.3709G>C p.E1237Q | Missense Mutation (SNP) | VAF 98/481 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58010384, COSV58019196; called by muse, mutect2, varscan2
- CD36 | c.845A>C p.D282A | Missense Mutation (SNP) | VAF 166/423 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV59215204; called by muse, mutect2, varscan2
- CD99L2 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 22/41 reads (54%) | catalogued as COSV100692040, COSV60937141; called by muse, varscan2
- CDAN1 | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51166623; called by muse, mutect2, varscan2
- CDC42BPG | c.1015G>T p.G339C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61348133; called by muse, mutect2, varscan2
- CDC5L | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65176548; called by muse, mutect2, varscan2
- CDH12 | c.281C>G p.S94* | Nonsense Mutation (SNP) | VAF 72/604 reads (12%) | catalogued as COSV66419682; called by muse, mutect2, varscan2
- CDH18 | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs779360240, COSV56936318; called by muse, mutect2, varscan2
- CDH19 | c.1451C>A p.S484Y | Missense Mutation (SNP) | VAF 86/189 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV50964206; called by muse, mutect2, varscan2
- CDK13 | c.2752C>G p.Q918E | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.18); catalogued as COSV51702651; called by muse, mutect2, varscan2
- CDK13 | c.4160C>T p.S1387F | Missense Mutation (SNP) | VAF 149/302 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV51702659; called by muse, mutect2, varscan2
- CDK19 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV60450790; called by muse, mutect2
- CDKN2A | c.448G>A p.G150S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as COSV58703319; called by muse, mutect2, varscan2
- CDON | c.2248C>G p.P750A | Missense Mutation (SNP) | VAF 97/234 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749742672, COSV54999681; called by muse, mutect2, varscan2
- CDYL2 | c.797C>G p.S266C | Missense Mutation (SNP) | VAF 187/426 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73654364; called by muse, mutect2, varscan2
- CEACAM8 | c.29G>T p.R10I | Missense Mutation (SNP) | VAF 70/488 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV54991077; called by muse, mutect2, varscan2
- CENPF | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 30/105 reads (29%) | catalogued as COSV104423678, COSV65276282; called by muse, mutect2
- CENPI | c.2225C>G p.S742C | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.747); catalogued as COSV54504056; called by muse, mutect2, varscan2
- CENPP | c.397T>A p.S133T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV65039612; called by muse, mutect2, varscan2
- CEP135 | c.3307G>A p.E1103K | Missense Mutation (SNP) | VAF 55/308 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57258744; called by muse, mutect2, varscan2
- CEP170 | c.2263del p.E755Rfs*62 | Frame Shift Del (DEL) | VAF 93/758 reads (12%) | catalogued as COSV60510266; called by mutect2, pindel, varscan2
- CFAP44 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 78/200 reads (39%) | catalogued as rs769673594, COSV55613144; called by muse, mutect2, varscan2
- CFHR5 | c.521C>A p.S174Y | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56820729, COSV56823902; called by muse, mutect2, varscan2
- CHAMP1 | c.1309C>G p.P437A | Missense Mutation (SNP) | VAF 70/115 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs201708961, COSV63522668; called by muse, mutect2, varscan2
- CHST5 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60340235; called by muse, mutect2, varscan2
- CLDN12 | c.452C>G p.S151C | Missense Mutation (SNP) | VAF 26/541 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs751390117, COSV55307277; called by muse, mutect2
- CLPB | c.894G>C p.M298I | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.178); catalogued as COSV53630998; called by muse, mutect2
- CNGB1 | c.242C>A p.S81Y | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.201); catalogued as COSV51903073; called by muse, mutect2, varscan2
- CNKSR2 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV54260398; called by muse, mutect2, varscan2
- CNTN1 | c.2378G>C p.G793A | Missense Mutation (SNP) | VAF 58/367 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61641836; called by muse, mutect2, varscan2
- CNTN4 | c.2281G>T p.V761L | Missense Mutation (SNP) | VAF 97/240 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV61871407, COSV61875748; called by muse, mutect2, varscan2
- COL11A1 | c.3088G>A p.G1030R | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62188436, COSV62202136; called by muse, mutect2, varscan2
- COL11A1 | c.1359G>T p.M453I | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as COSV62188445, COSV62199669; called by muse, mutect2, varscan2
- COL12A1 | c.8257G>T p.G2753C | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59399853; called by muse, mutect2, varscan2
- COL15A1 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 27/128 reads (21%) | catalogued as COSV66646854; called by muse, mutect2, varscan2
- COL15A1 | c.4049C>T p.T1350M | Missense Mutation (SNP) | VAF 96/344 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.287); catalogued as rs374842979; called by muse, mutect2, varscan2
- COL21A1 | c.486G>C p.K162N | Missense Mutation (SNP) | VAF 87/236 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.129); catalogued as COSV55169605, COSV99778542; called by muse, mutect2, varscan2
- COL22A1 | c.3176A>G p.K1059R | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.82); catalogued as rs1308579402, COSV57343415; called by muse, mutect2
- COL22A1 | c.516C>G p.I172M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.084); catalogued as COSV57345019; called by muse, mutect2, varscan2
- COL24A1 | c.924G>C p.Q308H | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.172); catalogued as COSV65308986; called by muse, varscan2
- COL24A1 | c.388A>G p.R130G | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV65308990; called by muse, mutect2, varscan2
- COL4A1 | c.2842G>T p.G948C | Missense Mutation (SNP) | VAF 94/195 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM130940, COSV65427944; called by muse, mutect2, varscan2
- COL4A1 | c.2841G>T p.K947N | Missense Mutation (SNP) | VAF 93/197 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65427948; called by muse, mutect2, varscan2
- COL5A2 | c.361G>C p.V121L | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.147); catalogued as rs754180974, COSV66411265; called by muse, mutect2, varscan2
- COL6A6 | c.4108C>T p.R1370W | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs371511195; called by muse, mutect2, varscan2
- COLEC12 | c.1870G>C p.E624Q | Missense Mutation (SNP) | VAF 24/385 reads (6%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.489); catalogued as COSV68371846; called by muse, mutect2
- COPA | c.2911C>G p.Q971E | Missense Mutation (SNP) | VAF 93/801 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54105097; called by muse, mutect2, varscan2
- COPA | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54105116; called by muse, mutect2
- COPB1 | c.1792T>C p.S598P | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51449298; called by muse, mutect2, varscan2
- CPAMD8 | c.3225G>T p.K1075N (on ENST00000651564; = p.K1028N on NM_015692.5) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.839); catalogued as COSV104437626; called by muse, mutect2, varscan2
- CPS1 | c.2546C>A p.T849K | Missense Mutation (SNP) | VAF 58/205 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV51802670; called by muse, varscan2
- CPS1 | c.2724G>T p.K908N | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51815402; called by muse, mutect2, varscan2
- CPS1 | c.3283G>A p.V1095I | Missense Mutation (SNP) | VAF 142/414 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV51815415; called by muse, mutect2, varscan2
- CPXCR1 | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV52163256; called by muse, mutect2, varscan2
- CRB1 | c.2472C>G p.I824M | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as COSV66331471, COSV66333925; called by muse, mutect2, varscan2
- CREG2 | c.793A>G p.I265V | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV61317250; called by muse, mutect2, varscan2
- CRLF3 | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 68/247 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV60836240; called by muse, mutect2, varscan2
- CRNN | c.522G>C p.Q174H | Missense Mutation (SNP) | VAF 110/385 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV55122730; called by muse, mutect2, varscan2
- CSMD1 | c.6757G>C p.A2253P (on ENST00000520002; = p.A2252P on NM_033225.6) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59344283; called by mutect2, varscan2
- CSMD2 | c.10117G>A p.G3373S | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53928731; called by muse, mutect2, varscan2
- CSMD3 | c.9853C>A p.Q3285K (on ENST00000297405 / NM_001363185.1; = p.Q3116K on NM_052900.3) | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV52229795, COSV52353222; called by muse, mutect2, varscan2
- CSMD3 | c.4087G>T p.G1363* (on ENST00000297405 / NM_001363185.1; = p.G1259* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 37/159 reads (23%) | catalogued as COSV52229810; called by muse, mutect2, varscan2
- CTLA4 | c.671G>T p.*224Lext*16 | Nonstop Mutation (SNP) | VAF 47/133 reads (35%) | catalogued as COSV55592633; called by muse, mutect2, varscan2
- CTNNA2 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.98); catalogued as COSV63564620; called by muse, varscan2
- CTSL | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58246650; called by muse, mutect2, varscan2
- CTSS | c.273G>C p.L91F | Missense Mutation (SNP) | VAF 36/474 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV64566580; called by muse, mutect2
- CUL3 | c.963G>C p.L321F | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52366698; called by muse, mutect2, varscan2
- CYFIP2 | c.1584T>A p.N528K | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.932); catalogued as COSV59043733; called by muse, mutect2, varscan2
- CYLC1 | c.967A>G p.K323E | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as COSV61413505; called by muse, mutect2, varscan2
- DARS2 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); catalogued as COSV53407704; called by muse, mutect2, varscan2
- DBI | c.28G>T p.A10S (on ENST00000355857 / NM_001079862.3; = p.A27S on NM_020548.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV58347298; called by muse, mutect2, varscan2
- DCBLD2 | c.1065G>C p.L355F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs1239054399, COSV58790962; called by muse, mutect2, varscan2
- DCX | c.374A>T p.Y125F | Missense Mutation (SNP) | VAF 155/258 reads (60%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as COSV57567999, COSV57571630; called by muse, mutect2, varscan2
- DDX53 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as rs1569253298, COSV60069515; called by muse, mutect2
- DICER1 | c.1671C>G p.I557M | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.268); catalogued as COSV58623138; called by muse, mutect2, varscan2
- DISC1 | c.2448G>C p.Q816H | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64103467, COSV64127008; called by muse, mutect2, varscan2
- DLG1 | c.2581G>C p.E861Q (on ENST00000419354 / NM_001290983.1; = p.E883Q on NM_004087.2) | Missense Mutation (SNP) | VAF 23/608 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV58382484, COSV58386042; called by muse, mutect2
- DLGAP1 | c.2584C>T p.H862Y | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.925); catalogued as COSV59816175; called by muse, mutect2, varscan2
- DLGAP1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs1432614866, COSV100229751, COSV59816231; called by muse, mutect2
- DLK1 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs755998526, COSV57992425; called by muse, mutect2, varscan2
- DMBT1 | c.7255C>A p.H2419N (on ENST00000338354 / NM_001377530.1; = p.H1662N on NM_004406.3) | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV57547527, COSV57549855; called by muse, mutect2, varscan2
- DMXL1 | c.4262C>G p.S1421* | Nonsense Mutation (SNP) | VAF 100/446 reads (22%) | catalogued as COSV60715491; called by muse, mutect2, varscan2
- DMXL1 | c.5206G>C p.D1736H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV60715497; called by muse, mutect2, varscan2
- DNAH7 | c.11586+2T>G p.X3862_splice | Splice Site (SNP) | VAF 22/195 reads (11%) | catalogued as COSV56772603; called by muse, mutect2, varscan2
- DNAH8 | c.6421C>G p.L2141V | Missense Mutation (SNP) | VAF 136/268 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs766688342, COSV59460261; called by muse, mutect2, varscan2
- DNAH9 | c.2993G>C p.R998T | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV52358655, COSV52376002; called by muse, mutect2, varscan2
- DNAH9 | c.5727C>A p.Y1909* | Nonsense Mutation (SNP) | VAF 23/68 reads (34%) | catalogued as COSV52358666; called by muse, mutect2, varscan2
- DNAJA4 | c.302G>C p.R101T (on ENST00000343789; = p.R130T on NM_018602.3) | Missense Mutation (SNP) | VAF 81/223 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.175); catalogued as COSV59426182; called by muse, mutect2, varscan2
- DNAJC13 | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV53453574; called by muse, mutect2, varscan2
- DNAJC13 | c.6650C>T p.T2217I | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53453589; called by muse, mutect2
- DNMBP | c.2930A>G p.Y977C | Missense Mutation (SNP) | VAF 117/248 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60628478; called by muse, mutect2, varscan2
- DOCK5 | c.3184G>C p.E1062Q | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as COSV52405477; called by muse, mutect2, varscan2
- DOCK6 | c.2884G>T p.G962* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV53917357; called by muse, mutect2, varscan2
- DOP1B | c.2843G>T p.S948I | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV67693498, COSV67694082; called by muse, mutect2, varscan2
- DPH2 | c.722G>T p.W241L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV52544033; called by muse, mutect2, varscan2
- DPH5 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs1407633692, COSV59859822; called by muse, mutect2, varscan2
- DPPA4 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV100169576, COSV59511410; called by muse, mutect2
- DPYSL3 | c.1698C>G p.I566M | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV58328303; called by muse, mutect2
- DST | c.20446G>C p.E6816Q (on ENST00000361203 / NM_001374722.1; = p.E4513Q on NM_015548.5) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV55024217, COSV99759320; called by muse, mutect2, varscan2
- DST | c.3052G>A p.D1018N (on ENST00000361203 / NM_001374722.1; = p.D692N on NM_001723.6) | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV55024232; called by muse, mutect2, varscan2
- DTNBP1 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV59038871; called by muse, mutect2, varscan2
- DYNC1H1 | c.10011G>T p.Q3337H | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV64138841; called by muse, mutect2
- EDEM3 | c.900G>T p.L300F | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.58); catalogued as COSV58925787; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 96/271 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs754312859, COSV62567475; called by muse, mutect2, varscan2
- EFCAB13 | c.71C>G p.S24C | Missense Mutation (SNP) | VAF 51/292 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV58945696, COSV58950054; called by muse, mutect2, varscan2
- EGFR | c.629-2A>G p.X210_splice | Splice Site (SNP) | VAF 66/1154 reads (6%) | catalogued as COSV51817116; called by muse, mutect2
- EHBP1 | c.894A>T p.K298N | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV50425126; called by muse, mutect2
- EIF4G3 | c.1462C>G p.Q488E | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); catalogued as COSV51675375; called by muse, mutect2
- EIPR1 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs376448610; called by muse, mutect2, varscan2
- ELF4 | c.594G>C p.R198S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV57453475; called by muse, mutect2, varscan2
- ENDOD1 | c.1420C>G p.L474V | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV53590052; called by muse, mutect2, varscan2
- EPB41L2 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61356955; called by muse, varscan2
- EPB41L3 | c.2989G>A p.D997N | Missense Mutation (SNP) | VAF 78/849 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1012123253, COSV59459326; called by muse, mutect2
- EPHA5 | c.2526C>G p.I842M | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56654517; called by muse, mutect2, varscan2
- EPHA6 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 35/472 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.442); catalogued as rs763378493, COSV67579596; called by muse, mutect2
- EPN1 | c.1538G>T p.G513V (on ENST00000270460 / NM_001321263.1; = p.G487V on NM_013333.3) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV50039749; called by muse, mutect2, varscan2
- EPS8 | c.1919C>G p.S640C | Missense Mutation (SNP) | VAF 151/347 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as COSV55533107; called by muse, mutect2, varscan2
- ERBB4 | c.2205T>G p.G735= | Splice Region (SNP) | VAF 18/71 reads (25%) | catalogued as COSV53549983; called by muse, varscan2
- ERICH3 | c.4138G>A p.D1380N | Missense Mutation (SNP) | VAF 113/565 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.301); catalogued as COSV58611038; called by muse, mutect2, varscan2
- ESAM | c.1153C>G p.Q385E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV54035729; called by muse, mutect2, varscan2
- ESYT1 | c.1534C>G p.Q512E | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as COSV57274579; called by muse, mutect2, varscan2
- EXOC1 | c.1148G>C p.R383T | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV62120951, COSV62120981; called by muse, mutect2, varscan2
- EXOC4 | c.2195C>T p.S732F | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV54106390; called by muse, mutect2
- F11 | c.1508C>G p.S503C | Missense Mutation (SNP) | VAF 95/298 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53002396; called by muse, mutect2, varscan2
- FAM114A1 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 170/389 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1220553530, COSV62673537; called by muse, mutect2, varscan2
- FAM114A2 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 101/360 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as COSV61078263; called by muse, mutect2, varscan2
- FAM135B | c.2367G>T p.K789N | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.023); catalogued as COSV52736169; called by muse, mutect2, varscan2
- FAM135B | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 25/498 reads (5%) | catalogued as COSV52725585; called by muse, mutect2
- FAM162A | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0.015); catalogued as COSV51658747; called by muse, mutect2, varscan2
- FAM216B | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV58270891; called by muse, mutect2
- FAM91A1 | c.1958G>A p.C653Y | Missense Mutation (SNP) | VAF 38/1031 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV58238025; called by muse, mutect2
- FAM98C | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.819); catalogued as COSV53039236, COSV53040103; called by muse, mutect2, varscan2
- FARP2 | c.113G>C p.R38T | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.157); catalogued as COSV50874124; called by muse, mutect2, varscan2
- FAT4 | c.9047G>T p.G3016V | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58694235; called by muse, mutect2, varscan2
- FBXO11 | c.1093G>A p.E365K (on ENST00000403359 / NM_001190274.2; = p.E281K on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 155/465 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV57022061; called by muse, mutect2, varscan2
- FBXO25 | c.507C>G p.I169M (on ENST00000382824 / NM_183421.2; = p.I102M on NM_012173.3) | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV52337711; called by muse, mutect2, varscan2
- FBXO27 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 240/464 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.188); catalogued as COSV53072693; called by muse, varscan2
- FBXW7 | c.2033C>G p.S678* (on ENST00000281708 / NM_001349798.2; = p.S598* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 40/173 reads (23%) | catalogued as COSV55897853; called by muse, mutect2, varscan2
- FCAR | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs867266528, COSV62029972, COSV62030183; called by muse, mutect2, varscan2
- FCRL3 | c.2171A>T p.N724I | Missense Mutation (SNP) | VAF 72/579 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63843046, COSV63845196; called by muse, mutect2, varscan2
- FDXACB1 | c.1351C>A p.R451S | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52786727, COSV52789352; called by muse, mutect2, varscan2
- FER1L6 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.058); catalogued as COSV67551190; called by muse, mutect2, varscan2
- FLG | c.1933C>G p.H645D | Missense Mutation (SNP) | VAF 146/371 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV64244016; called by muse, mutect2, varscan2
- FLT1 | c.1337T>A p.L446Q | Missense Mutation (SNP) | VAF 71/115 reads (62%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.832); catalogued as COSV56732848; called by muse, mutect2, varscan2
- FOS | c.824C>A p.P275Q | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV57839842; called by muse, mutect2, varscan2
- FOXF1 | c.387G>T p.E129D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV52287250; called by muse, varscan2
- FRA10AC1 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV63272770; called by muse, mutect2, varscan2
- FRAS1 | c.917G>A p.C306Y | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168727642, COSV53624389; called by muse, mutect2, varscan2
- FRMD3 | c.1705G>C p.E569Q | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV58464246; called by muse, mutect2
- FRMPD2 | c.2031G>C p.Q677H | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV100563399, COSV59719832; called by muse, mutect2, varscan2
- FRY | c.4648G>A p.E1550K | Missense Mutation (SNP) | VAF 53/85 reads (62%) | SIFT tolerated (0.62); PolyPhen benign (0.281); catalogued as COSV66573315; called by muse, mutect2, varscan2
- FRYL | c.4069G>C p.G1357R | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51952221, COSV99977118; called by muse, mutect2, varscan2
- FSCB | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV61218690; called by muse, mutect2
- FUBP1 | c.1576+1del p.X526_splice | Splice Site (DEL) | VAF 27/119 reads (23%) | catalogued as COSV53930058; called by mutect2, pindel, varscan2
- G2E3 | c.890A>T p.K297I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV52841326; called by muse, mutect2, varscan2
- GABRA1 | c.313A>T p.K105* | Nonsense Mutation (SNP) | VAF 32/164 reads (20%) | catalogued as COSV50109648; called by muse, mutect2, varscan2
- GALNT12 | c.1621C>T p.H541Y | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.063); catalogued as COSV66662315, COSV66663283; called by muse, mutect2, varscan2
- GALNT18 | c.657C>A p.F219L | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57152247; called by muse, mutect2, varscan2
- GARNL3 | c.1001G>A p.R334K | Missense Mutation (SNP) | VAF 90/422 reads (21%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.472); catalogued as COSV59228006; called by muse, mutect2, varscan2
- GCN1 | c.6163G>A p.E2055K | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs751679365, COSV56110335; called by muse, mutect2, varscan2
- GCNT3 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as COSV68531961, COSV68532273; called by muse, mutect2, varscan2
- GCSAM | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 62/836 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV58263806; called by muse, mutect2
- GLB1L | c.1290C>G p.F430L | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55477347; called by muse, mutect2, varscan2
- GLRB | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV52418823, COSV52419681; called by muse, mutect2, varscan2
- GLS2 | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57665721; called by muse, mutect2
- GLT1D1 | c.985G>T p.E329* (on ENST00000442111 / NM_001366889.1; = p.E249* on NM_144669.3) | Nonsense Mutation (SNP) | VAF 93/357 reads (26%) | catalogued as COSV55883947; called by muse, mutect2, varscan2
- GLYATL1 | c.472C>A p.P158T (on ENST00000317391 / NM_001354699.1; = p.P189T on NM_080661.4) | Missense Mutation (SNP) | VAF 127/405 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs766739429, COSV55609837; called by muse, mutect2, varscan2
- GNA12 | c.784A>C p.M262L | Missense Mutation (SNP) | VAF 68/241 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV51742735; called by muse, mutect2, varscan2
- GNPTAB | c.2044G>T p.D682Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV68449756; called by muse, mutect2, varscan2
- GP2 | c.841G>C p.A281P (on ENST00000381362 / NM_001007240.3; = p.A278P on NM_001502.4) | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.864); catalogued as COSV56895020; called by muse, mutect2
- GPANK1 | c.546G>T p.Q182H | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV63263914; called by muse, mutect2, varscan2
- GPC5 | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 79/138 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV65609541; called by muse, mutect2, varscan2
- GPR1 | c.286T>G p.Y96D | Missense Mutation (SNP) | VAF 111/383 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67977095; called by muse, mutect2, varscan2
- GPR156 | c.1587G>C p.E529D | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV59940951; called by muse, mutect2, varscan2
- GPR18 | c.945C>G p.F315L | Missense Mutation (SNP) | VAF 74/196 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs762415931, COSV61621329; called by muse, mutect2, varscan2
- GPR45 | c.809T>A p.L270Q | Missense Mutation (SNP) | VAF 111/487 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51524784; called by muse, mutect2, varscan2
- GPR61 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV68177806; called by muse, mutect2, varscan2
- GPRIN3 | c.2203A>G p.I735V | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs749356839, COSV60885433; called by muse, mutect2, varscan2
- GRAMD1C | c.89C>G p.P30R | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.209); catalogued as COSV63983185; called by muse, mutect2
- GREM2 | c.304A>C p.N102H | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58953169; called by muse, mutect2, varscan2
- GRID2 | c.248G>T p.C83F | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56225657; called by muse, mutect2, varscan2
- GRIK1 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV58723612; called by muse, mutect2, varscan2
- GRM5 | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV59599864; called by muse, mutect2
- GSN | c.710G>C p.R237T | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV57998823, COSV58001210; called by muse, mutect2
- H2AC20 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 30/313 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58612490, COSV58612937; called by muse, mutect2, varscan2
- H2AC8 | c.225G>C p.K75N | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs563842312, COSV55127248, COSV99773116; called by muse, mutect2, varscan2
- H3C7 | c.237C>G p.F79L | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.349); catalogued as COSV55100302; called by muse, mutect2, varscan2
- HECA | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV62769872; called by muse, mutect2, varscan2
- HERC2 | c.3553G>A p.E1185K | Missense Mutation (SNP) | VAF 31/347 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV55332740; called by muse, mutect2
- HGD | c.1320C>A p.N440K | Missense Mutation (SNP) | VAF 107/604 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52199373; called by muse, mutect2, varscan2
- HIBCH | c.525C>G p.F175L | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62891742, COSV62892730; called by muse, mutect2
- HIVEP2 | c.3400G>T p.D1134Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV50021994; called by muse, mutect2, varscan2
- HIVEP3 | c.2726G>A p.R909H | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56018158; called by muse, mutect2, varscan2
- HLA-A | c.896-1G>C p.X299_splice | Splice Site (SNP) | VAF 15/45 reads (33%) | catalogued as COSV65139440; called by muse, mutect2, varscan2
- HLTF | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV59501934; called by muse, mutect2
- HMCN1 | c.15905G>C p.R5302T | Missense Mutation (SNP) | VAF 145/384 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV54914582; called by muse, mutect2, varscan2
- HOOK1 | c.1695G>C p.Q565H | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV64619001, COSV64619605; called by muse, mutect2, varscan2
- HOXC6 | c.570G>T p.Q190H | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54537442; called by muse, mutect2, varscan2
- HRG | c.1262C>G p.P421R | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV51645578, COSV51646419; called by muse, mutect2, varscan2
- HSPA9 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV51865163; called by muse, mutect2
- HUWE1 | c.8177C>G p.S2726* | Nonsense Mutation (SNP) | VAF 20/270 reads (7%) | catalogued as COSV53352970; called by muse, mutect2
- IFNB1 | c.414G>C p.M138I | Missense Mutation (SNP) | VAF 53/358 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.448); catalogued as COSV66525548; called by muse, mutect2, varscan2
- IGHMBP2 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV54823811; called by muse, mutect2, varscan2
- IGSF5 | c.554C>G p.S185* | Nonsense Mutation (SNP) | VAF 23/92 reads (25%) | catalogued as rs748941524, COSV66029335; called by muse, mutect2, varscan2
- IGSF8 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.462); catalogued as rs144014563; called by muse, mutect2, varscan2
- IL13RA1 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.865); catalogued as COSV100861553, COSV65424700; called by muse, mutect2, varscan2
- IL17RE | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV55969301, COSV55970617; called by muse, mutect2, varscan2
- ILRUN | c.754C>T p.P252S (on ENST00000374023 / NM_024294.4; = p.P186S on NM_022758.6) | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.085); catalogued as COSV64990577; called by muse, mutect2
- INPP4B | c.2637G>A p.M879I | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764114435, COSV53732336; called by muse, mutect2, varscan2
- INPP4B | c.2329C>G p.L777V | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV53732360; called by muse, mutect2, varscan2
- INTS3 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 83/212 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV59679195; called by muse, mutect2, varscan2
- JMJD1C | c.3995G>C p.R1332T | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV59516455; called by muse, mutect2, varscan2
- KALRN | c.5041G>T p.E1681* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | catalogued as COSV62567133, COSV62571404; called by muse, mutect2, varscan2
- KBTBD6 | c.300C>G p.F100L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65271578; called by muse, mutect2, varscan2
- KDM5B | c.3971C>T p.S1324L | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV52509624; called by muse, mutect2, varscan2
- KDM5B | c.3799C>T p.Q1267* | Nonsense Mutation (SNP) | VAF 51/173 reads (29%) | catalogued as rs1270198556, COSV52509637; called by muse, mutect2, varscan2
- KDM5B | c.3409G>C p.E1137Q | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV52509660; called by muse, varscan2
- KDM5B | c.3045G>C p.Q1015H | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV52507506, COSV52509673; called by muse, mutect2, varscan2
- KDM5B | c.2232G>A p.M744I | Missense Mutation (SNP) | VAF 147/426 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as rs1343902808, COSV52509682; called by muse, mutect2, varscan2
- KDM5B | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 92/286 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.058); catalogued as rs1264779837, COSV52509690; called by muse, varscan2
- KDM8 | c.105G>T p.L35F | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV53730423; called by muse, mutect2, varscan2
- KIAA0586 | c.70G>A p.E24K (on ENST00000619416 / NM_001244190.2; = p.E39K on NM_014749.5) | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV53621876; called by muse, mutect2
- KIAA1958 | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61725200; called by muse, mutect2, varscan2
- KIAA1958 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.824); catalogued as COSV61725211; called by muse, mutect2, varscan2
- KIF21A | c.2497C>G p.L833V (on ENST00000361418 / NM_001378440.1; = p.L820V on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as rs979633626, COSV62767266, COSV62777812; called by muse, mutect2, varscan2
- KIF4B | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 119/260 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV70528391, COSV70530194; called by muse, mutect2, varscan2
- KIF5C | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV69172288; called by muse, mutect2, varscan2
- KIRREL2 | c.168G>A p.W56* | Nonsense Mutation (SNP) | VAF 5/99 reads (5%) | catalogued as COSV52877731; called by muse, mutect2
- KLHL4 | c.1422T>G p.I474M | Missense Mutation (SNP) | VAF 93/152 reads (61%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.857); catalogued as COSV64144332; called by muse, mutect2, varscan2
- KMT2C | c.3281A>G p.Y1094C | Missense Mutation (SNP) | VAF 87/226 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51460004; called by muse, mutect2, varscan2
- KMT2D | c.4130A>G p.Q1377R | Missense Mutation (SNP) | VAF 91/281 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56458012, COSV56488509; called by muse, mutect2, varscan2
- KMT2E | c.4508C>T p.A1503V | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as COSV57576070; called by muse, mutect2, varscan2
- KNG1 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs779764784, COSV53979073, COSV53979592; called by mutect2, varscan2
- KNTC1 | c.1344G>C p.Q448H | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV61079406; called by muse, mutect2, varscan2
- KRT12 | c.374A>T p.E125V | Missense Mutation (SNP) | VAF 26/364 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52431480; called by muse, mutect2
- KRT28 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs769997190, COSV60685630; called by muse, mutect2, varscan2
- KRTAP10-5 | c.593C>A p.S198* | Nonsense Mutation (SNP) | VAF 236/874 reads (27%) | catalogued as COSV59954524, COSV59968821; called by muse, mutect2, varscan2
- KTN1 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV68024209; called by muse, mutect2
- KY | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 21/40 reads (53%) | catalogued as COSV71017914; called by muse, mutect2, varscan2
- LAMA1 | c.6206G>C p.R2069T | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.14); catalogued as COSV101055576, COSV67539611; called by muse, mutect2, varscan2
- LAMA1 | c.1617C>G p.I539M | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1306260317, COSV67539615; called by muse, varscan2
- LAMC1 | c.4212G>C p.K1404N | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV51151217; called by muse, mutect2, varscan2
- LARGE1 | c.1351T>C p.F451L | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61665335; called by muse, mutect2, varscan2
- LDAH | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 90/1441 reads (6%) | SIFT tolerated (0.99); PolyPhen benign (0.01); catalogued as COSV52971561; called by muse, mutect2
- LDB3 | c.1983C>A p.Y661* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV53944846; called by muse, mutect2, varscan2
- LDHC | c.451A>G p.S151G | Missense Mutation (SNP) | VAF 155/321 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55004835; called by muse, mutect2, varscan2
- LDLRAD4 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.969); catalogued as rs748709104, COSV63339590; called by muse, varscan2
- LMBRD2 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV56951086; called by muse, mutect2, varscan2
- LMNTD1 | c.563del p.S188Ffs*10 | Frame Shift Del (DEL) | VAF 337/1728 reads (20%) | catalogued as COSV51445447; called by mutect2, pindel, varscan2
- LPIN2 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 108/1576 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55241315; called by muse, mutect2
- LRFN5 | c.632C>G p.P211R | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53264242; called by muse, mutect2, varscan2
- LRP1B | c.9625G>T p.V3209F | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs77794732, COSV67231336, COSV67250866, COSV67284629; called by muse, mutect2
- LRP3 | c.290A>T p.H97L | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT tolerated (0.31); PolyPhen benign (0.248); catalogued as COSV53505222; called by muse, mutect2, varscan2
- LRRC29 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV58527641; called by muse, mutect2, varscan2
- LRRC32 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs748881614, COSV52633859; called by mutect2, varscan2
- LRRC4C | c.1727C>A p.T576K | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.122); catalogued as COSV53425400, COSV53430470; called by muse, mutect2
- LRRC66 | c.1374C>G p.F458L | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV58632876, COSV58635285; called by muse, mutect2, varscan2
- LRRFIP1 | c.1918G>A p.E640K (on ENST00000392000 / NM_001137552.2; = p.E616K on NM_004735.4) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); catalogued as COSV55253435; called by muse, mutect2, varscan2
- LYST | c.5039C>G p.S1680* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV67709403; called by muse, mutect2, varscan2
- MACROD2 | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV54009198, COSV54011633; called by muse, mutect2, varscan2
- MAGEA6 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 108/205 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs782213540, COSV61449170; called by muse, mutect2
- MAGEA6 | c.905C>A p.P302Q | Missense Mutation (SNP) | VAF 110/212 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV61449165; called by muse, mutect2
- MAPKAPK5 | c.635C>A p.S212* | Nonsense Mutation (SNP) | VAF 91/297 reads (31%) | catalogued as COSV72431641; called by muse, mutect2, varscan2
- MAZ | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50716363; called by muse, mutect2, varscan2
- MBD4 | c.1501G>C p.E501Q | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV51445056; called by muse, mutect2
- MBLAC1 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs768084664, COSV53542825, COSV53542932; called by mutect2, varscan2
- MCC | c.305G>C p.R102P | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.24); catalogued as COSV68727485, COSV68728447; called by muse, mutect2, varscan2
- MCF2L2 | c.1595G>C p.R532P | Missense Mutation (SNP) | VAF 40/742 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61048520; called by muse, mutect2
- MCOLN3 | c.474C>G p.I158M | Missense Mutation (SNP) | VAF 81/335 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.136); catalogued as COSV62014920; called by muse, mutect2, varscan2
- MDP1 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 30/560 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV51660992; called by muse, mutect2
- ME2 | c.1623C>G p.F541L | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1181168227, COSV58423938; called by muse, mutect2
- MECOM | c.163G>A p.E55K (on ENST00000468789 / NM_001105078.4; = p.E243K on NM_004991.4) | Missense Mutation (SNP) | VAF 184/919 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0.024); catalogued as rs1002948185, COSV52958465, COSV52964959; called by muse, mutect2, varscan2
- MED13L | c.6032A>T p.N2011I | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV56123752; called by muse, mutect2, varscan2
- MEP1A | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 64/175 reads (37%) | catalogued as COSV57921183; called by muse, mutect2, varscan2
- MGAM | c.2423G>T p.G808V | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.224); catalogued as COSV72075008; called by muse, mutect2, varscan2
- MIA3 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV60514695; called by muse, mutect2, varscan2
- MINAR1 | c.1495A>C p.S499R | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV59584313; called by muse, mutect2, varscan2
- MIS18A | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.153); catalogued as COSV51589578; called by muse, mutect2, varscan2
- MME | c.952G>T p.G318W | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV64708581; called by muse, mutect2, varscan2
- MMP19 | c.736G>C p.D246H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59452046; called by muse, mutect2, varscan2
- MOGS | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV51970387; called by muse, mutect2
- MON2 | c.3410G>A p.G1137E | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.455); catalogued as COSV54809940; called by muse, mutect2, varscan2
- MPHOSPH9 | c.3402G>T p.R1134S | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56619692; called by muse, mutect2
- MPHOSPH9 | c.3238G>C p.E1080Q | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100187400, COSV56621420; called by muse, mutect2
- MRPL37 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 48/247 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60322087; called by muse, mutect2, varscan2
- MSH5 | c.249G>C p.E83D | Missense Mutation (SNP) | VAF 161/457 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV65210284; called by muse, mutect2, varscan2
- MSH6 | c.457+1G>T p.X153_splice | Splice Site (SNP) | VAF 8/96 reads (8%) | catalogued as COSV52282504; called by muse, mutect2
- MTHFD1 | c.1891C>G p.P631A | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53701680; called by muse, mutect2, varscan2
- MTNR1B | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 141/546 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs1201633065, COSV57067279; called by muse, mutect2, varscan2
- MUC3A | c.9231G>A p.L3077= | Splice Region (SNP) | VAF 5/41 reads (12%) | catalogued as COSV60219221; called by muse, mutect2, varscan2
- MYBBP1A | c.2968A>T p.N990Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV54593995, COSV54599737; called by muse, mutect2, varscan2
- MYCBP2 | c.4459C>T p.Q1487* (on ENST00000357337; = p.Q1525* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 20/344 reads (6%) | catalogued as COSV62027269; called by muse, mutect2
- MYF5 | c.266C>G p.T89S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57355600, COSV99953472; called by muse, mutect2, varscan2
- MYH14 | c.5187G>C p.E1729D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.308); catalogued as COSV51823264; called by muse, mutect2
- MYH15 | c.2310T>A p.F770L | Missense Mutation (SNP) | VAF 94/546 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV56313768; called by muse, mutect2, varscan2
- MYH2 | c.1844C>G p.S615C | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV55441754; called by muse, mutect2, varscan2
- MYH8 | c.5658G>T p.E1886D | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV67967876; called by muse, mutect2
- MYH8 | c.1291G>T p.A431S | Missense Mutation (SNP) | VAF 333/766 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as COSV67967884; called by muse, mutect2, varscan2
- MYLK | c.2430G>T p.M810I | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as COSV60614302; called by muse, mutect2
- MYO10 | c.1870G>T p.A624S | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.289); catalogued as COSV72563231; called by muse, mutect2, varscan2
- MYO1E | c.580C>G p.L194V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV55690286; called by muse, mutect2, varscan2
- MYOM1 | c.4140G>T p.V1380= | Splice Region (SNP) | VAF 20/267 reads (7%) | catalogued as COSV55295070; called by muse, mutect2
- MYOM1 | c.2261C>T p.S754L | Missense Mutation (SNP) | VAF 28/323 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs751348038, COSV55295078; called by muse, mutect2
- MYPN | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV62735373; called by muse, mutect2, varscan2
- NAA11 | c.409T>C p.Y137H | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1433253231, COSV54514956; called by muse, mutect2, varscan2
- NARS2 | c.1104T>G p.N368K | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV55253261; called by muse, mutect2
- NCBP1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV64317016; called by muse, mutect2
- NCBP3 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50108622; called by muse, mutect2, varscan2
- NCEH1 | c.571C>A p.P191T (on ENST00000538775; = p.P151T on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/506 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56435654; called by muse, mutect2
- NCKAP1L | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 48/564 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV53208945; called by muse, mutect2
- NCOR1 | c.530C>G p.S177* | Nonsense Mutation (SNP) | VAF 15/287 reads (5%) | catalogued as COSV51969297, COSV51982809; called by muse, mutect2
- NCR1 | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52557350, COSV99401054; called by muse, mutect2, varscan2
- NDNF | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV65633382; called by muse, mutect2, varscan2
- NEB | c.11965G>A p.D3989N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50836356; called by muse, mutect2, varscan2
- NLGN4X | c.1601G>A p.G534D | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52008771, COSV52025322; called by muse, mutect2, varscan2
- NLRP14 | c.3193G>A p.A1065T | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.163); catalogued as COSV55068996; called by muse, mutect2
- NLRP3 | c.2242G>T p.D748Y | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.722); catalogued as COSV60227428; called by muse, mutect2
- NLRP7 | c.2186G>T p.G729V (on ENST00000340844 / NM_206828.3; = p.G701V on NM_139176.3) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV60176901; called by muse, mutect2, varscan2
- NME7 | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV63168343; called by muse, mutect2, varscan2
- NME7 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 192/382 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs139755731; called by muse, mutect2, varscan2
- NMI | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 11/132 reads (8%) | catalogued as COSV54638509; called by muse, mutect2
- NODAL | c.297C>G p.S99R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV54661861; called by muse, mutect2, varscan2
- NOTCH3 | c.1732C>G p.R578G | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.972); catalogued as CM961047, COSV54639394, COSV54646154, COSV54650741; called by muse, mutect2, varscan2
- NPHP3 | c.1519G>C p.E507Q | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV58631419; called by muse, mutect2, varscan2
- NR1H4 | c.402T>A p.D134E (on ENST00000551379 / NM_001206993.2; = p.D124E on NM_005123.4) | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51853825; called by muse, mutect2, varscan2
- NR1H4 | c.530del p.G177Afs*4 (on ENST00000551379 / NM_001206993.2; = p.G167Afs*4 on NM_005123.4) | Frame Shift Del (DEL) | VAF 59/160 reads (37%) | catalogued as rs1566461780; called by mutect2, pindel, varscan2
- NSUN6 | c.1325C>A p.A442D | Missense Mutation (SNP) | VAF 40/420 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV56627463, COSV56634101; called by muse, mutect2
- NT5DC1 | c.1345G>C p.D449H | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV60309931; called by muse, mutect2, varscan2
- NUP155 | c.3947G>C p.R1316T (on ENST00000231498 / NM_153485.3; = p.R1257T on NM_004298.4) | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV51531671; called by muse, mutect2, varscan2
- NUP205 | c.6029C>G p.S2010* | Nonsense Mutation (SNP) | VAF 22/364 reads (6%) | catalogued as COSV53658954; called by muse, mutect2
- NUTM1 | c.1315C>G p.L439V | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.166); catalogued as COSV59217625; called by muse, mutect2, varscan2
- NWD1 | c.4130C>A p.A1377E | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV60345499; called by muse, mutect2
- OPN5 | c.999-2A>G p.X333_splice | Splice Site (SNP) | VAF 62/155 reads (40%) | catalogued as COSV55246273; called by muse, mutect2, varscan2
- OR11H1 | c.650T>A p.F217Y | Missense Mutation (SNP) | VAF 21/309 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.219); catalogued as COSV53272166; called by muse, mutect2
- OR13D1 | c.52C>A p.H18N | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.08); catalogued as COSV59514221; called by muse, mutect2, varscan2
- OR1B1 | c.480G>T p.L160F | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV59171967; called by muse, mutect2, varscan2
- OR2G6 | c.529A>T p.I177F | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58575039; called by muse, mutect2, varscan2
- OR2T29 | c.50T>G p.I17S | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV60771641; called by muse, mutect2, varscan2
- OR4A15 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 122/507 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as COSV59036112; called by muse, mutect2, varscan2
- OR51M1 | c.269T>A p.L90* | Nonsense Mutation (SNP) | VAF 291/657 reads (44%) | catalogued as COSV60784899; called by muse, mutect2, varscan2
- OR52E4 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 121/254 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV57625336; called by muse, mutect2, varscan2
- OR5H15 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62948504, COSV62948786; called by muse, mutect2, varscan2
- OR5I1 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs1205164658, COSV56886384, COSV56887803; called by muse, mutect2, varscan2
- OR5J2 | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.984); catalogued as COSV56620763, COSV56622138; called by muse, mutect2, varscan2
- OR5K2 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 44/305 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV71143292; called by muse, mutect2, varscan2
- OR5M11 | c.433A>T p.T145S | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV73141917; called by muse, varscan2
- OR5M11 | c.376T>A p.Y126N | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV73141918; called by muse, varscan2
- OR5T3 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 258/792 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs987291844, COSV100282946, COSV57381541; called by muse, varscan2
- OR5W2 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60616895; called by muse, mutect2
- OR6F1 | c.868T>A p.Y290N | Missense Mutation (SNP) | VAF 149/504 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57468416; called by muse, mutect2, varscan2
- OR6K2 | c.493C>A p.L165M | Missense Mutation (SNP) | VAF 222/670 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.941); catalogued as COSV62743745; called by muse, mutect2, varscan2
- OR7C2 | c.802A>G p.R268G | Missense Mutation (SNP) | VAF 100/296 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as COSV50181099; called by muse, mutect2, varscan2
- OR7D4 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs775480123, COSV58071313; called by muse, mutect2
- ORAI3 | c.355C>A p.L119M | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as COSV52689639; called by muse, mutect2
- ORC1 | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 84/290 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV65364398; called by muse, mutect2, varscan2
- P2RY4 | c.569G>C p.R190P | Missense Mutation (SNP) | VAF 70/128 reads (55%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.665); catalogued as COSV100997065, COSV65736844; called by muse, mutect2, varscan2
- P2RY4 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 70/125 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as rs770348089, COSV65736764; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.524A>T p.K175M (on ENST00000259318 / NM_001136562.3; = p.K406M on NM_007203.5) | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52178497; called by muse, mutect2, varscan2
- PAN3 | c.1630C>G p.Q544E | Missense Mutation (SNP) | VAF 17/313 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.546); catalogued as rs1364587052, COSV56704773; called by muse, mutect2
- PAPPA2 | c.2141G>T p.G714V | Missense Mutation (SNP) | VAF 125/1123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62781095; called by muse, mutect2, varscan2
- PARS2 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV64883718; called by muse, mutect2, varscan2
- PBRM1 | c.2467G>C p.D823H | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV56285767; called by muse, mutect2, varscan2
- PCDH15 | c.3466G>A p.D1156N | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as CM1515076, COSV57342165; called by muse, mutect2, varscan2
- PCDH15 | c.1399C>T p.Q467* | Nonsense Mutation (SNP) | VAF 33/237 reads (14%) | catalogued as COSV57335661; called by muse, mutect2, varscan2
- PCDHA12 | c.976G>C p.G326R | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56520025; called by muse, mutect2, varscan2
- PCDHGB7 | c.937G>C p.E313Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.139); catalogued as COSV53978726; called by muse, mutect2, varscan2
- PCDHGB7 | c.2294T>G p.F765C | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV53978738, COSV99542467; called by muse, mutect2, varscan2
- PCLO | c.9286C>G p.P3096A | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61646449; called by muse, mutect2
- PCNX1 | c.3643C>T p.Q1215* | Nonsense Mutation (SNP) | VAF 58/188 reads (31%) | catalogued as COSV53097156; called by muse, mutect2, varscan2
- PDE2A | c.2328C>G p.I776M | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57809623; called by muse, mutect2, varscan2
- PDILT | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV56702961; called by muse, mutect2
- PER1 | c.3592G>C p.D1198H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57920621; called by muse, varscan2
- PEX5L | c.890C>G p.S297C | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV55849619; called by muse, mutect2, varscan2
- PFDN5 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 166/450 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.092); catalogued as COSV54476384; called by muse, mutect2, varscan2
- PHACTR4 | c.1960C>G p.Q654E (on ENST00000373839 / NM_001350159.2; = p.Q664E on NM_023923.4) | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as COSV65784471; called by muse, mutect2, varscan2
- PHAX | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV52551612; called by muse, mutect2, varscan2
- PHF3 | c.2848G>T p.V950L | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV50324763; called by muse, mutect2
- PHLDB2 | c.388C>G p.H130D | Missense Mutation (SNP) | VAF 72/943 reads (8%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.006); catalogued as COSV67313211; called by muse, mutect2
- PIBF1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs1442175728, COSV58325073; called by muse, mutect2, varscan2
- PIH1D2 | c.250C>G p.H84D | Missense Mutation (SNP) | VAF 21/259 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV54775847; called by muse, mutect2
- PIK3CG | c.2121A>T p.R707S | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV63250077; called by muse, mutect2, varscan2
- PIK3R4 | c.2239A>T p.M747L | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV63242005; called by muse, mutect2, varscan2
- PKD1L1 | c.8015T>G p.L2672R | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as COSV51843404; called by muse, mutect2
- PKDREJ | c.4807G>A p.G1603S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.617); catalogued as rs546954517, COSV53550541; called by muse, mutect2, varscan2
- PKHD1 | c.2059C>G p.Q687E | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV61883804; called by muse, mutect2, varscan2
- PKHD1L1 | c.1942C>A p.P648T | Missense Mutation (SNP) | VAF 76/264 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs777191851, COSV65746729; called by muse, mutect2, varscan2
- PKNOX1 | c.1027C>G p.Q343E | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV52337406; called by muse, mutect2, varscan2
- PKNOX1 | c.1269C>G p.H423Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV52337424; called by muse, mutect2, varscan2
- PLA2G7 | c.677C>A p.A226E | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51262368; called by muse, mutect2, varscan2
- PLAAT2 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as COSV55375126; called by muse, mutect2
- PLB1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV59829510; called by muse, mutect2, varscan2
- PLCB1 | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 31/347 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62041673, COSV62055698, COSV62058096; called by muse, mutect2, varscan2
- PLCXD3 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV60611922; called by muse, mutect2, varscan2
- PLCZ1 | c.928A>T p.R310* | Nonsense Mutation (SNP) | VAF 41/70 reads (59%) | catalogued as COSV56855378; called by muse, mutect2, varscan2
- PLD1 | c.2048C>T p.S683F | Missense Mutation (SNP) | VAF 61/509 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.809); catalogued as COSV60570111; called by muse, mutect2, varscan2
- PLD1 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 36/606 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV60570120; called by muse, mutect2
- PLEKHG1 | c.3641C>G p.S1214* | Nonsense Mutation (SNP) | VAF 13/242 reads (5%) | catalogued as COSV62048739; called by muse, mutect2
- PLEKHG2 | c.3194A>T p.Q1065L | Missense Mutation (SNP) | VAF 91/537 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV52686114; called by muse, mutect2, varscan2
- PLEKHM1 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.052); catalogued as COSV69599158; called by muse, mutect2, varscan2
- PLEKHM1 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 12/94 reads (13%) | catalogued as COSV69599162; called by muse, varscan2
- PLEKHM2 | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV53817580; called by muse, varscan2
- PLK3 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59500276; called by muse, mutect2, varscan2
- PLXNC1 | c.1229C>G p.S410* | Nonsense Mutation (SNP) | VAF 14/112 reads (13%) | catalogued as rs752253626, COSV51576415, COSV51578205; called by muse, mutect2, varscan2
- PMFBP1 | c.2593G>T p.D865Y (on ENST00000537465; = p.D860Y on NM_031293.3) | Missense Mutation (SNP) | VAF 118/270 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52820613, COSV52826991; called by muse, mutect2, varscan2
- PNLIP | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as COSV65041092; called by muse, mutect2
- POC5 | c.942G>C p.Q314H (on ENST00000428202 / NM_001099271.2; = p.Q289H on NM_152408.2) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV62807605; called by muse, mutect2, varscan2
- POM121 | c.3693G>C p.K1231N (on ENST00000434423; = p.K966N on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57518998, COSV99988539; called by muse, mutect2, varscan2
- POM121C | c.1122G>C p.L374F (on ENST00000607367; = p.L132F on NM_001099415.3) | Missense Mutation (SNP) | VAF 40/464 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV57547224; called by muse, mutect2
- POTEH | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as rs777074196, COSV100625312; called by muse, mutect2, varscan2
- PPIP5K2 | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as COSV58607056; called by muse, mutect2
- PPIP5K2 | c.3175C>T p.H1059Y | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.112); catalogued as COSV58607066; called by muse, mutect2
- PPM1L | c.716G>C p.R239T | Missense Mutation (SNP) | VAF 26/479 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV55566449, COSV55570748; called by muse, mutect2
- PPP1R3A | c.2066G>C p.R689T | Missense Mutation (SNP) | VAF 384/1121 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs756846229, COSV52884795; called by mutect2, varscan2
- PPP2R1B | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV59253913; called by muse, mutect2, varscan2
- PRDM10 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.458); catalogued as COSV58802597; called by muse, mutect2, varscan2
- PRDM9 | c.1475G>A p.R492K | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as COSV57004487; called by muse, mutect2, varscan2
- PREX1 | c.2922C>G p.I974M | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV64253715; called by muse, mutect2, varscan2
- PRKCI | c.846G>C p.M282I | Missense Mutation (SNP) | VAF 13/232 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV55520332; called by muse, mutect2
- PRMT7 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 169/367 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs753947184, COSV59834142; called by muse, mutect2, varscan2
- PRMT9 | c.1891G>C p.E631Q | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1161459556, COSV59360306, COSV59361389; called by muse, mutect2
- PROKR2 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773364376, COSV54085515; called by muse, mutect2, varscan2
- PRRC2C | c.2008C>T p.Q670* (on ENST00000367742; = p.Q668* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 34/769 reads (4%) | catalogued as COSV58907965; called by muse, mutect2
- PRSS12 | c.2588C>G p.S863* | Nonsense Mutation (SNP) | VAF 128/254 reads (50%) | catalogued as COSV56607631; called by muse, mutect2, varscan2
- PSG1 | c.1217C>A p.S406Y | Missense Mutation (SNP) | VAF 129/752 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV54952596; called by muse, mutect2, varscan2
- PSG5 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 73/348 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV61654589; called by muse, mutect2, varscan2
- PSIP1 | c.1211G>C p.R404P | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV66254784, COSV66255077; called by muse, mutect2, varscan2
- PSMD3 | c.1446C>A p.F482L | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52858491; called by muse, mutect2, varscan2
- PTBP2 | c.1066G>C p.E356Q (on ENST00000426398 / NM_001300986.2; = p.E348Q on NM_021190.4) | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); catalogued as COSV64625343; called by muse, mutect2, varscan2
- PTPN13 | c.5422C>T p.Q1808* (on ENST00000411767 / NM_080683.3; = p.Q1789* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV57411018; called by mutect2, varscan2
- PTPRF | c.4380T>G p.C1460W | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63446393; called by muse, mutect2, varscan2
- PTPRN2 | c.2356C>T p.R786W | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201790422, COSV101234354, COSV67026755; called by muse, mutect2
- PTPRN2 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373081454; called by muse, mutect2, varscan2
- PTPRO | c.2921A>G p.Y974C (on ENST00000281171 / NM_030667.3; = p.Y946C on NM_002848.4) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55514732; called by muse, varscan2
- PWWP3A | c.349G>C p.D117H (on ENST00000627377; = p.D116H on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.424); catalogued as COSV60903094; called by muse, mutect2, varscan2
- PWWP3A | c.587G>C p.G196A (on ENST00000627377; = p.G195A on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.121); catalogued as COSV60903102; called by muse, mutect2, varscan2
- PWWP3B | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 121/182 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV61800499; called by muse, mutect2, varscan2
- PXDNL | c.3903C>A p.D1301E | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62477590; called by muse, mutect2, varscan2
- PXYLP1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs573740092, COSV53891711; called by muse, mutect2, varscan2
- R3HDM1 | c.773G>C p.R258T | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51527253; called by muse, mutect2
- RAB33A | c.484C>A p.P162T | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV57062415; called by muse, mutect2, varscan2
- RAD51AP2 | c.1063A>G p.S355G | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs1191191413, COSV67587375, COSV67588476; called by muse, varscan2
- RALGAPB | c.1142dup p.H382Tfs*2 | Frame Shift Ins (INS) | VAF 10/82 reads (12%) | catalogued as rs756557178; called by mutect2, varscan2
- RANBP2 | c.8651C>T p.S2884L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV51703548; called by muse, mutect2, varscan2
- RANBP9 | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 42/430 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV50582693; called by muse, mutect2
- RAP1GAP | c.1072G>T p.G358W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51574431; called by muse, mutect2, varscan2
- RAPGEF1 | c.1482G>C p.Q494H | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV64700528; called by muse, mutect2, varscan2
- RAPGEF4 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs757476344, COSV51399996; called by muse, mutect2, varscan2
- RARS2 | c.678C>G p.F226L | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV65761701; called by muse, mutect2
- RASA1 | c.2691-2A>G p.X897_splice | Splice Site (SNP) | VAF 51/101 reads (50%) | catalogued as COSV57197958; called by muse, mutect2, varscan2
- RASA2 | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 136/383 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV53937816, COSV53942611; called by muse, mutect2, varscan2
- RASAL1 | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55657517; called by muse, mutect2
- RBM11 | c.713A>G p.D238G | Missense Mutation (SNP) | VAF 53/331 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV68748203; called by muse, mutect2, varscan2
- RDH12 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 30/466 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV50821460; called by muse, mutect2
- RHOBTB2 | c.2096G>A p.R699Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs763030083, COSV52392974; called by muse, mutect2, varscan2
- RIC1 | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 109/241 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.047); catalogued as rs765742639, COSV52611634; called by muse, mutect2, varscan2
- RIMKLA | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.055); catalogued as COSV68909842; called by muse, mutect2
- RNF115 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs186281231, COSV65165090; called by muse, mutect2, varscan2
- RNF207 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1367951949, COSV65007894; called by muse, mutect2, varscan2
- RNF41 | c.753C>A p.H251Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61504646; called by muse, mutect2, varscan2
- RNF6 | c.1337C>G p.S446C | Missense Mutation (SNP) | VAF 15/297 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60419537; called by muse, mutect2
- ROS1 | c.6886G>A p.E2296K | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs761155034, COSV63857239; called by muse, mutect2, varscan2
- ROS1 | c.2213A>G p.E738G | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.722); catalogued as COSV63857250; called by muse, mutect2, varscan2
- RP1 | c.4963C>T p.Q1655* | Nonsense Mutation (SNP) | VAF 30/239 reads (13%) | catalogued as COSV55118307; called by muse, mutect2, varscan2
- RPAP3 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 87/405 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs768816369, COSV50042185; called by muse, mutect2, varscan2
- RPH3A | c.622G>C p.D208H (on ENST00000389385 / NM_001143854.2; = p.D204H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/330 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.143); catalogued as COSV66991912; called by muse, mutect2, varscan2
- RPS18 | c.411G>C p.K137N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV65851871; called by muse, mutect2, varscan2
- RREB1 | c.4530G>T p.R1510S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58560554; called by muse, mutect2, varscan2
- RSBN1 | c.2058C>G p.F686L | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV54733487; called by muse, mutect2, varscan2
- RSBN1L | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 31/570 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV58506432; called by muse, mutect2
- RTL5 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 46/67 reads (69%) | catalogued as COSV65454037; called by muse, mutect2, varscan2
- RTN1 | c.1593G>T p.Q531H | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV50731625; called by muse, mutect2, varscan2
- RTP2 | c.71C>A p.A24E | Missense Mutation (SNP) | VAF 54/413 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.239); catalogued as COSV100832942, COSV64079200; called by muse, mutect2, varscan2
- RYR3 | c.2158T>G p.W720G | Missense Mutation (SNP) | VAF 193/635 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66798023; called by muse, mutect2, varscan2
- SAMD7 | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV59419724; called by muse, mutect2, varscan2
- SAMD9L | c.599A>T p.K200I | Missense Mutation (SNP) | VAF 289/946 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59082943; called by muse, mutect2, varscan2
- SCG5 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 136/519 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs201757263, COSV55707160; called by muse, mutect2, varscan2
- SCN1A | c.5664G>C p.Q1888H (on ENST00000303395 / NM_001202435.3; = p.Q1877H on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV57666973, COSV57676226; called by muse, mutect2
- SCN8A | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.98); catalogued as COSV61977476; called by muse, mutect2
- SCP2 | c.856A>T p.R286* | Nonsense Mutation (SNP) | VAF 53/262 reads (20%) | catalogued as COSV65261581; called by muse, mutect2, varscan2
- SDK2 | c.5763G>C p.Q1921H | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV66190265; called by muse, mutect2, varscan2
- SEC31A | c.152C>G p.S51C | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV58876367; called by muse, mutect2, varscan2
- SEC63 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 58/203 reads (29%) | catalogued as COSV64600730, COSV64601435; called by muse, mutect2, varscan2
- SELL | c.936G>C p.K312N (on ENST00000650983; = p.K299N on NM_000655.5) | Missense Mutation (SNP) | VAF 139/286 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV52551894, COSV52552999; called by muse, mutect2, varscan2
- SELP | c.1465G>A p.V489M | Missense Mutation (SNP) | VAF 118/231 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV55254314; called by muse, mutect2, varscan2
- SEMA3C | c.1643+1G>A p.X548_splice | Splice Site (SNP) | VAF 20/296 reads (7%) | catalogued as COSV54849811; called by muse, mutect2
- SEMA4F | c.1411C>G p.Q471E | Missense Mutation (SNP) | VAF 75/404 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV60284048; called by muse, mutect2, varscan2
- SFN | c.147G>C p.K49N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59433648; called by muse, mutect2, varscan2
- SFTPA1 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 122/600 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV64867366; called by muse, mutect2, varscan2
- SGSM1 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV68511462; called by mutect2, varscan2
- SGSM3 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763920663, COSV50653414; called by muse, mutect2, varscan2
- SH2D2A | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 338/1299 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.069); catalogued as COSV63885047, COSV63885457; called by muse, mutect2, varscan2
- SI | c.2318G>A p.W773* | Nonsense Mutation (SNP) | VAF 159/448 reads (35%) | catalogued as COSV52286660; called by muse, mutect2, varscan2
- SIAH1 | c.451C>G p.Q151E | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV53523722; called by muse, mutect2
- SKAP1 | c.866G>C p.R289P | Missense Mutation (SNP) | VAF 163/465 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV61148448; called by muse, mutect2, varscan2
- SLAMF6 | c.778C>G p.Q260E | Missense Mutation (SNP) | VAF 44/749 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.275); catalogued as COSV63587551; called by muse, mutect2
- SLC12A1 | c.1699A>G p.I567V | Missense Mutation (SNP) | VAF 123/385 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66796800; called by muse, mutect2, varscan2
- SLC12A1 | c.3052C>A p.P1018T | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV66796806; called by muse, mutect2, varscan2
- SLC12A2 | c.1218C>G p.I406M | Missense Mutation (SNP) | VAF 117/562 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV52473282; called by muse, mutect2, varscan2
- SLC13A1 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV52013580; called by muse, mutect2, varscan2
- SLC15A3 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57172386; called by muse, mutect2, varscan2
- SLC18B1 | c.697G>C p.A233P | Missense Mutation (SNP) | VAF 106/393 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.13); catalogued as COSV51595090; called by muse, mutect2, varscan2
- SLC25A40 | c.799C>G p.L267V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV62020715; called by muse, mutect2, varscan2
- SLC26A8 | c.2374G>A p.V792M | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs115071158; called by muse, mutect2, varscan2
- SLC30A4 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as rs754695518, COSV56006630; called by muse, mutect2, varscan2
- SLC46A2 | c.1208C>G p.S403C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV65290166; called by muse, mutect2, varscan2
- SLC49A4 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 114/305 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV53746286, COSV53748397; called by muse, mutect2, varscan2
- SLC5A9 | c.302C>A p.A101D | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52584363; called by muse, mutect2, varscan2
- SLC6A15 | c.2060C>G p.S687C | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV57025792; called by muse, mutect2, varscan2
- SLC7A14 | c.944C>A p.T315N | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV51585123; called by muse, mutect2
- SLCO1B3 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53935134; called by muse, varscan2
- SLIT1 | c.435C>G p.I145M | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV56592781; called by muse, mutect2, varscan2
- SLITRK3 | c.1493C>G p.A498G | Missense Mutation (SNP) | VAF 18/269 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53850011, COSV99579248; called by muse, mutect2
- SLITRK5 | c.1915C>A p.P639T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV61523945; called by mutect2, varscan2
- SMARCD1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV57318841; called by muse, mutect2, varscan2
- SMC5 | c.2534C>T p.T845I | Missense Mutation (SNP) | VAF 113/927 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.683); catalogued as COSV63193889; called by muse, mutect2, varscan2
- SMCHD1 | c.1937G>A p.G646E | Missense Mutation (SNP) | VAF 89/862 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55261300; called by muse, mutect2
- SMCHD1 | c.4008G>T p.R1336S | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as COSV55261349; called by muse, mutect2
- SMG1 | c.9298C>T p.Q3100* | Nonsense Mutation (SNP) | VAF 90/256 reads (35%) | catalogued as COSV67172911; called by muse, mutect2, varscan2
- SMYD5 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as COSV50265243; called by muse, mutect2, varscan2
- SNAP25 | c.603G>C p.K201N | Missense Mutation (SNP) | VAF 138/507 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV54773624; called by muse, mutect2, varscan2
- SNX10 | c.384A>T p.E128D | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.222); catalogued as COSV58401546; called by muse, mutect2, varscan2
- SORCS1 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as COSV53880380, COSV53904652; called by muse, mutect2
- SOS2 | c.3610C>T p.P1204S | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV53569812; called by muse, mutect2
- SPAG17 | c.2478G>A p.M826I | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60458494; called by muse, mutect2, varscan2
- SPTA1 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 62/282 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as COSV100935435, COSV63755992; called by muse, mutect2, varscan2
- SPTLC2 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 16/500 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV53641607; called by muse, mutect2
- ST8SIA4 | c.1037G>C p.R346T | Missense Mutation (SNP) | VAF 14/155 reads (9%) | PolyPhen benign (0.078); catalogued as COSV51512494; called by muse, mutect2
- STK31 | c.2827C>G p.L943V | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as rs1016611430, COSV63457481; called by muse, mutect2
- STN1 | c.678G>T p.Q226H | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as COSV56545160; called by muse, mutect2, varscan2
- SULT1C2 | c.642G>C p.K214N | Missense Mutation (SNP) | VAF 106/334 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV52265636; called by muse, varscan2
- SYN3 | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 37/311 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV60502072, COSV60510898, COSV60511090; called by muse, mutect2, varscan2
- SYNDIG1 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1418311992, COSV65233241, COSV65234846; called by muse, mutect2, varscan2
- SYNE1 | c.9189G>T p.Q3063H (on ENST00000367255 / NM_182961.4; = p.Q3070H on NM_033071.3) | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV55025209; called by muse, mutect2, varscan2
- SYNE2 | c.14008G>A p.E4670K | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1330613504, COSV59941985, COSV59956923; called by muse, mutect2, varscan2
- SYNE3 | c.1539G>C p.E513D | Missense Mutation (SNP) | VAF 152/288 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV62080574; called by muse, varscan2
- SZT2 | c.8641G>A p.E2881K (on ENST00000634258 / NM_001365999.1; = p.E2824K on NM_015284.4) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.049); catalogued as COSV65171349; called by muse, mutect2, varscan2
- TAAR2 | c.229C>G p.P77A (on ENST00000367931 / NM_001033080.1; = p.P32A on NM_014626.3) | Missense Mutation (SNP) | VAF 84/347 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759731776, COSV51579433; called by muse, mutect2, varscan2
- TAPBP | c.68C>G p.A23G | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV56470857; called by muse, mutect2, varscan2
- TBC1D1 | c.3364G>T p.E1122* | Nonsense Mutation (SNP) | VAF 51/195 reads (26%) | catalogued as COSV54722241; called by muse, mutect2, varscan2
- TBX22 | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 142/259 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64786441, COSV64786765; called by muse, mutect2, varscan2
- TCEAL5 | c.510G>C p.W170C | Missense Mutation (SNP) | VAF 229/786 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV65503199; called by muse, mutect2, varscan2
- TCF4 | c.1603G>C p.D535H | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61896759; called by muse, mutect2
- TEFM | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58976183; called by muse, mutect2
- TEKT4 | c.642G>C p.E214D | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs143585686; called by muse, mutect2, varscan2
- TENM4 | c.8283G>C p.M2761I | Missense Mutation (SNP) | VAF 115/1073 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV53643102; called by muse, mutect2, varscan2
- TENT4A | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1242001776, COSV50096769; called by muse, mutect2, varscan2
- TEP1 | c.3219C>A p.R1073= | Splice Region (SNP) | VAF 54/401 reads (13%) | catalogued as COSV52995296; called by muse, mutect2, varscan2
- TET1 | c.596C>A p.S199Y | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV65386274; called by muse, mutect2, varscan2
- TEX13B | c.454C>A p.H152N | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV57203272, COSV57203471; called by muse, mutect2, varscan2
- TFDP2 | c.775G>A p.E259K (on ENST00000489671 / NM_001178139.2; = p.E199K on NM_006286.5) | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57705862; called by muse, mutect2
- TFIP11 | c.2174C>A p.P725Q | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53226798; called by muse, mutect2
- TGFB1I1 | c.964G>C p.D322H (on ENST00000394863 / NM_001042454.3; = p.D305H on NM_015927.4) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV62358430; called by muse, mutect2, varscan2
- TGFB2 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100859913, COSV65110021; called by muse, mutect2, varscan2
- THEMIS | c.705G>T p.M235I | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV64069337, COSV64072160; called by muse, mutect2, varscan2
- THG1L | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as COSV51452481; called by muse, mutect2, varscan2
- THRA | c.35C>G p.S12* | Nonsense Mutation (SNP) | VAF 15/111 reads (14%) | catalogued as COSV52844516; called by muse, mutect2, varscan2
- THRAP3 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs780723624, COSV63566679; called by muse, mutect2, varscan2
- THSD7A | c.2946G>T p.L982F | Missense Mutation (SNP) | VAF 40/715 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.342); catalogued as COSV70264266; called by muse, mutect2
- TLN2 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs780454196, COSV60891714; called by muse, mutect2, varscan2
- TMEM132D | c.3254G>A p.C1085Y | Missense Mutation (SNP) | VAF 36/494 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs751593339, COSV67160325, COSV67160978; called by muse, mutect2
- TMEM135 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 80/502 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59702583; called by muse, mutect2, varscan2
- TMEM192 | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.209); catalogued as rs553668773, COSV100121965, COSV60585545; called by muse, mutect2, varscan2
- TMEM53 | c.698A>T p.E233V | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as COSV59191086; called by muse, mutect2, varscan2
- TNIP1 | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as COSV59308170; called by muse, mutect2, varscan2
- TNRC6B | c.5179C>G p.L1727V (on ENST00000454349 / NM_001162501.2; = p.L1617V on NM_015088.3) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs746928822, COSV57300354; called by muse, mutect2, varscan2
- TNS1 | c.3934C>T p.P1312S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV50720544; called by muse, mutect2, varscan2
- TPP1 | c.778G>T p.V260L | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV54994620; called by muse, mutect2, varscan2
- TPR | c.4604G>C p.R1535T | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV66602673; called by muse, mutect2
- TRANK1 | c.5829C>A p.F1943L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57155180, COSV57155548; called by muse, mutect2, varscan2
- TRDN | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); catalogued as COSV62125605; called by muse, mutect2, varscan2
- TREM2 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58295089; called by muse, mutect2, varscan2
- TRIM17 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.04); catalogued as COSV52858650; called by muse, mutect2, varscan2
- TRIM51 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 17/246 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); catalogued as COSV55267990; called by muse, mutect2
- TRIM60 | c.1158G>A p.W386* | Nonsense Mutation (SNP) | VAF 49/117 reads (42%) | catalogued as COSV61970962; called by muse, mutect2, varscan2
- TRIP12 | c.5456A>T p.E1819V | Missense Mutation (SNP) | VAF 81/316 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV52267263; called by muse, mutect2, varscan2
- TRIP12 | c.5455G>T p.E1819* | Nonsense Mutation (SNP) | VAF 80/313 reads (26%) | catalogued as COSV52267270; called by muse, mutect2, varscan2
- TRMT2A | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV52814114; called by mutect2, varscan2
- TRO | c.1631T>A p.F544Y | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV51503829; called by muse, mutect2, varscan2
- TRPC4AP | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52681630; called by muse, mutect2, varscan2
- TRPM2 | c.1525C>T p.Q509* | Nonsense Mutation (SNP) | VAF 28/95 reads (29%) | catalogued as COSV55972253; called by muse, mutect2, varscan2
- TRPM7 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57918743; called by muse, mutect2
- TRPV1 | c.274A>C p.T92P | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV51520534; called by muse, mutect2, varscan2
- TSHZ2 | c.1803G>C p.K601N | Missense Mutation (SNP) | VAF 38/398 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV61589723, COSV61590270, COSV61590733; called by muse, mutect2
- TSHZ2 | c.1978G>C p.E660Q | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100295818, COSV61589727; called by muse, mutect2, varscan2
- TTN | c.81325G>A p.E27109K (on ENST00000591111; = p.E19685K on NM_003319.4) | Missense Mutation (SNP) | VAF 22/364 reads (6%) | PolyPhen benign (0.443); catalogued as COSV60167942, COSV60168101; called by muse, mutect2
- TTN | c.74839G>C p.E24947Q (on ENST00000591111; = p.E17523Q on NM_003319.4) | Missense Mutation (SNP) | VAF 15/295 reads (5%) | PolyPhen benign (0.344); catalogued as COSV60167962; called by muse, mutect2
- TULP3 | c.640G>C p.D214H | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376478642; called by muse, mutect2, varscan2
- UBA6 | c.1087G>T p.E363* | Nonsense Mutation (SNP) | VAF 54/271 reads (20%) | catalogued as COSV59178822; called by muse, mutect2, varscan2
- UBAP2L | c.1906G>C p.E636Q | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.979); catalogued as COSV55176261; called by muse, mutect2, varscan2
- UBE2J1 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV70561808; called by muse, mutect2
- UBE2R2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as rs113727596; called by muse, mutect2, varscan2
- UBE4A | c.3173G>A p.R1058K (on ENST00000252108 / NM_001204077.2; = p.R1065K on NM_004788.4) | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as COSV52805224; called by muse, mutect2, varscan2
- UBQLN3 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61164693; called by muse, mutect2, varscan2
- UBXN4 | c.681G>C p.E227D | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1469010370, COSV55635858; called by muse, mutect2
- UGT2B10 | c.679A>G p.N227D | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs777777554, COSV99608885; called by muse, varscan2
- UGT2B4 | c.1285C>A p.L429M | Missense Mutation (SNP) | VAF 40/399 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV59318171, COSV59318315; called by muse, mutect2, varscan2
- UNC13A | c.4161G>C p.E1387D | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53200520, COSV99407537; called by muse, mutect2, varscan2
- USH2A | c.2726C>A p.P909H | Missense Mutation (SNP) | VAF 210/702 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs752748453, COSV56393365; called by muse, mutect2, varscan2
- UTRN | c.5008C>G p.Q1670E | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV62340026; called by muse, mutect2
- VAC14 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55755160; called by muse, mutect2, varscan2
- VAV1 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); catalogued as COSV58386776; called by muse, mutect2, varscan2
- VCPIP1 | c.3199A>G p.T1067A | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.015); catalogued as COSV60048822; called by muse, mutect2, varscan2
- VEGFC | c.913G>C p.G305R | Missense Mutation (SNP) | VAF 93/206 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54600959; called by muse, mutect2, varscan2
- VPS13A | c.2335G>C p.D779H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62432739; called by muse, mutect2, varscan2
- VPS54 | c.2641C>T p.P881S | Missense Mutation (SNP) | VAF 82/255 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); catalogued as COSV55442402; called by muse, mutect2, varscan2
- VRTN | c.284G>T p.W95L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.341); catalogued as COSV56439102, COSV56442057; called by muse, varscan2
- VWA3A | c.1485G>C p.W495C | Missense Mutation (SNP) | VAF 36/484 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55392490; called by muse, mutect2
- VWA3B | c.2751C>G p.I917M | Missense Mutation (SNP) | VAF 124/434 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.283); catalogued as COSV68244297; called by muse, mutect2, varscan2
- VWCE | c.2755C>T p.R919C | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as rs927814868, COSV57112142; called by muse, mutect2, varscan2
- WDHD1 | c.372G>C p.M124I | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV62214668; called by muse, mutect2, varscan2
- WDR12 | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs866771277, COSV53687693, COSV53688527; called by muse, mutect2
- WDR70 | c.1571C>T p.T524I | Missense Mutation (SNP) | VAF 46/589 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV54276727; called by muse, mutect2
- WDR76 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV55478089; called by muse, mutect2
- WIPF2 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 14/162 reads (9%) | catalogued as COSV60274423; called by muse, mutect2
- WNK1 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs866991411, COSV60037883; called by muse, mutect2, varscan2
- WNK1 | c.3793G>A p.E1265K (on ENST00000315939 / NM_018979.4; = p.E1018K on NM_014823.3) | Missense Mutation (SNP) | VAF 40/338 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60037903; called by muse, mutect2, varscan2
- XPNPEP3 | c.571C>G p.L191V | Missense Mutation (SNP) | VAF 82/245 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV64027431; called by muse, mutect2, varscan2
- XRRA1 | c.1987C>G p.L663V | Missense Mutation (SNP) | VAF 129/1104 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV55133656; called by muse, mutect2, varscan2
- ZBTB2 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.899); catalogued as rs143773461; called by muse, mutect2, varscan2
- ZBTB41 | c.1664C>T p.S555L | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV66359409; called by muse, mutect2, varscan2
- ZBTB41 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 33/433 reads (8%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV66359411; called by muse, mutect2
- ZC4H2 | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62004652; called by muse, mutect2, varscan2
- ZCCHC14 | c.1677G>C p.M559I (on ENST00000268616; = p.M696I on NM_015144.3) | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV51887795; called by muse, mutect2, varscan2
- ZMYM3 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV58737145; called by mutect2, varscan2
- ZMYM4 | c.1037A>G p.K346R | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV58913129; called by muse, mutect2, varscan2
- ZNF135 | c.1651G>T p.E551* (on ENST00000313434 / NM_001289401.2; = p.E563* on NM_003436.4) | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | catalogued as COSV57883558; called by muse, mutect2, varscan2
- ZNF169 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs536175880, COSV61765115; called by muse, mutect2, varscan2
- ZNF221 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.167); catalogued as rs781600241, COSV52110059; called by muse, mutect2, varscan2
- ZNF227 | c.329C>G p.S110* | Nonsense Mutation (SNP) | VAF 32/119 reads (27%) | catalogued as COSV57311506; called by muse, mutect2, varscan2
- ZNF230 | c.462C>G p.I154M | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.302); catalogued as COSV71273332; called by muse, mutect2
- ZNF236 | c.3637C>G p.H1213D | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53491474; called by muse, mutect2, varscan2
- ZNF254 | c.166G>C p.V56L | Missense Mutation (SNP) | VAF 109/297 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV60054711; called by muse, mutect2, varscan2
- ZNF274 | c.723G>C p.W241C (on ENST00000610905; = p.W136C on NM_016324.3) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.889); catalogued as COSV58765335; called by muse, mutect2, varscan2
- ZNF285 | c.975C>G p.F325L | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.312); catalogued as COSV58409124; called by muse, mutect2, varscan2
- ZNF440 | c.1156C>G p.H386D | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58371629; called by muse, mutect2
- ZNF470 | c.1237A>T p.I413F | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV57969620; called by mutect2, varscan2
- ZNF479 | c.830C>A p.A277D | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs1340227088, COSV58640457; called by muse, mutect2, varscan2
- ZNF485 | c.151G>T p.G51W | Missense Mutation (SNP) | VAF 35/410 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62424738; called by muse, mutect2
313 further variants in this file (53 protein-altering or splice-affecting, 233 silent, 27 other) are not listed here.
